Surgical pathology report (de-identified scan), TCGA case TCGA-B9-4617, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-4617-01A (Primary Tumor).

Diagnosis:

[REDACTED]
[REDACTED] : [REDACTED]
Kidney, left, partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, papillary type

Histologic grade (if applicable): Fuhrman grade 2 (of 4)

Tumor size (greatest dimension): 2.4 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Minimal perirenal adipose tissue is present and is negative for carcinoma; tumor invades the renal capsule.

Gerota's fascia: Negative for carcinoma

Renal vein: Not present

Ureter: Not present

Venous (large vessel) Negative for carcinoma

Lymphatic (small vessel): Negative for carcinoma

Histologic assessment of surgical margins: Tumor is 2 mm from black inked renal parenchymal margin

Lymph nodes: Not present

Other significant findings: Chronic inflammation and mild glomerulosclerosis

AJCC Staging:

pT1a

pNx

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

Urinary retention.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left partial nephrectomy." It consists of a 14.9 gram, 4.5 x 3.5 x 2.5 cm partial nephrectomy. The capsule is inked blue and the parenchyma is inked black. The specimen is serially sectioned to reveal a well demarcated pale tan soft mass measuring 2.4 x 2.3 x 2.0 cm. Tumor is given to Tissue Procurement. The mass is entirely submitted in blocks A1-A7.

Source: NCI Genomic Data Commons file 369cae10-510b-493d-aded-ddb8f3e5f8dc (TCGA-B9-4617.3C77B727-3817-4324-AD5C-29B2CDD9C84E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).